Somatic mutation profile of tumor specimen TCGA-V4-A9EE-01A (aliquot TCGA-V4-A9EE-01A-11D-A39W-08) from TCGA case TCGA-V4-A9EE, project TCGA-UVM (Uveal Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Epithelioid cell melanoma; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIB; Age at diagnosis: 86.0 years (31,421 days).
Specimen TCGA-V4-A9EE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7ebf5d64-3b71-4d34-bfd5-e2a014664dad.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-V4-A9EE-10A (Blood Derived Normal), aliquot TCGA-V4-A9EE-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1738500a-6084-4310-9984-bab21a5b63f8

The open-access MAF lists 19 somatic variants for this specimen: 14 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 13, Silent 5, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAQ | c.626A>C p.Q209P | Missense Mutation (SNP) | VAF 37/69 reads (54%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121913492, COSV54105903, COSV54105914, COSV54108414; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- EVC | c.1987C>T p.R663W | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs867240492, COSV53830752; called by muse, mutect2
- GLA | c.892A>G p.N298D | Missense Mutation (SNP) | VAF 82/96 reads (85%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as CM960774; called by muse, mutect2, varscan2
- OR51B6 | c.236T>C p.V79A | Missense Mutation (SNP) | VAF 46/76 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.35); catalogued as rs779749567; called by muse, mutect2, varscan2
- PMPCA | c.1311G>A p.M437I | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1489517685; called by muse, mutect2, varscan2
- SLC26A9 | c.971C>T p.S324L | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs769381035, COSV61602420; called by muse, mutect2, varscan2
- ZBTB7B | c.613C>T p.R205W (on ENST00000292176; = p.R239W on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs199978828; called by muse, mutect2, varscan2
- DSTN | c.94_98del p.R32Efs*33 | Frame Shift Del (DEL) | VAF 18/71 reads (25%) | called by pindel, varscan2
- FBN1 | c.6212C>T p.S2071L | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- FBN1 | c.6211T>C p.S2071P | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- HDAC5 | c.2772G>C p.W924C | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIF13B | c.1136G>A p.R379Q | Missense Mutation (SNP) | VAF 29/51 reads (57%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- SBK2 | c.979C>T p.R327C | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.01); called by muse, mutect2
- ZNF157 | c.653T>C p.F218S | Missense Mutation (SNP) | VAF 30/34 reads (88%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); called by muse, mutect2, varscan2
- CHAT | c.1662C>T p.Y554= | Silent (SNP) | VAF 33/83 reads (40%) | catalogued as rs145370753; called by muse, mutect2, varscan2
- EFL1 | c.1245C>T p.S415= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as rs771171710, COSV51603821; called by muse, mutect2, varscan2
- MTNR1B | c.171C>A p.G57= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as rs938370725; called by muse, mutect2, varscan2
- RGS12 | c.2652G>A p.L884= | Silent (SNP) | VAF 16/43 reads (37%) | called by muse, mutect2, varscan2
- TBC1D10A | c.744G>A p.L248= | Silent (SNP) | VAF 32/66 reads (48%) | called by muse, mutect2, varscan2
